Somatic mutation profile of tumor specimen TCGA-A7-A6VV-01A (aliquot TCGA-A7-A6VV-01A-22D-A33E-09) from TCGA case TCGA-A7-A6VV, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 51.2 years (18,695 days).
Specimen TCGA-A7-A6VV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 834c20ca-a255-4e06-b31a-72879130e494.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A7-A6VV-10A (Blood Derived Normal), aliquot TCGA-A7-A6VV-10A-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec9557a1-7800-490e-8241-c33e8c26f88d

The open-access MAF lists 50 somatic variants for this specimen: 37 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 10, Frame Shift Del 2, 3'UTR 2, Nonsense Mutation 2, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB5 | c.1067C>A p.A356D | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV51709744; called by muse, mutect2, varscan2
- ABCC4 | c.3144C>A p.F1048L | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.05); catalogued as COSV65320033; called by muse, mutect2
- AP1B1 | c.2125G>A p.V709M | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.36); catalogued as rs202101776, COSV100434914; called by muse, mutect2, varscan2
- CCR9 | c.977G>A p.R326Q (on ENST00000357632 / NM_031200.3; = p.R314Q on NM_006641.4) | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.74); PolyPhen benign (0.044); catalogued as rs201410158, COSV100591752, COSV62939882; called by muse, mutect2, varscan2
- DYRK1A | c.1245C>A p.Y415* | Nonsense Mutation (SNP) | VAF 17/52 reads (33%) | catalogued as COSV58296286; called by muse, mutect2, varscan2
- EIF2AK4 | c.236G>A p.C79Y | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99775584; called by muse, mutect2, varscan2
- FAM83C | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as rs149089081, COSV65582447; called by muse, varscan2
- HK1 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as rs963045215, COSV53862677; called by muse, mutect2
- IRF2BPL | c.1129G>C p.D377H | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99468584; called by muse, mutect2
- ITGB1 | c.548-1G>A p.X183_splice | Splice Site (SNP) | VAF 5/34 reads (15%) | catalogued as COSV100172170; called by muse, mutect2, varscan2
- KIFC2 | c.838C>G p.Q280E | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0.018); catalogued as COSV100024041; called by muse, mutect2, varscan2
- KLHL12 | c.265del p.D89Tfs*10 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | catalogued as COSV100766185; called by mutect2, pindel, varscan2
- KMT2C | c.14433C>A p.N4811K | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as COSV100078283; called by muse, mutect2, varscan2
- MMEL1 | c.1966G>C p.G656R | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs767949894, COSV99984652; called by muse, mutect2, varscan2
- MYO1C | c.1661G>C p.S554T (on ENST00000648651 / NM_001080779.2; = p.S519T on NM_033375.5) | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.14); catalogued as COSV100704615; called by muse, mutect2, varscan2
- MYO1F | c.3110C>A p.P1037H | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100596688, COSV100597198; called by muse, mutect2, varscan2
- MYO6 | c.2687A>G p.Q896R | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs753343273, COSV100889447; called by muse, mutect2, varscan2
- NECTIN3 | c.264G>C p.Q88H | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100162842, COSV60549826; called by muse, mutect2, varscan2
- NTF4 | c.572G>T p.R191L | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100032348; called by muse, mutect2, varscan2
- PLPPR1 | c.556C>A p.L186M | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs768378346, COSV66453691; called by muse, mutect2, varscan2
- PREX2 | c.3073A>G p.I1025V | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99910096; called by muse, mutect2, varscan2
- PRKDC | c.5745G>C p.L1915F | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100043511; called by muse, mutect2, varscan2
- RABGEF1 | c.851C>T p.A284V (on ENST00000439720 / NM_001287061.2; = p.A271V on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770537510, COSV99535262; called by muse, mutect2, varscan2
- RAD21 | c.1627G>T p.D543Y | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.67); catalogued as COSV99815724; called by muse, mutect2, varscan2
- RRP1B | c.542G>A p.G181E | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100513301, COSV61479225; called by muse, mutect2, varscan2
- SLC12A7 | c.1073A>G p.Q358R | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV99370785; called by muse, mutect2, varscan2
- SLC6A14 | c.390C>G p.I130M | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64146381; called by muse, mutect2, varscan2
- SLC7A6OS | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV99862416; called by muse, mutect2
- SLCO1C1 | c.1469T>A p.M490K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV99860234; called by muse, mutect2, varscan2
- THSD7A | c.3896C>T p.S1299F | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV69855958; called by muse, mutect2, varscan2
- TP53 | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 18/32 reads (56%) | catalogued as COSV52734084, COSV53134595; called by muse, mutect2, varscan2
- TRIM50 | c.1238G>A p.R413H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs868915961, COSV99392649; called by muse, mutect2
- TTC7B | c.559C>T p.L187F | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100128802; called by muse, mutect2, varscan2
- ZNF433 | c.520G>C p.E174Q | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.649); catalogued as COSV100795066; called by muse, mutect2, varscan2
- ENPP2 | c.1151C>A p.T384N (on ENST00000075322 / NM_001040092.3; = p.T436N on NM_006209.5) | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.09); called by muse, mutect2
- HNF1B | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZEB2 | c.173_188del p.Q58Lfs*12 | Frame Shift Del (DEL) | VAF 10/51 reads (20%) | called by mutect2, pindel, varscan2
- ABCB5 | c.1068C>A p.A356= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV99330158; called by muse, mutect2, varscan2
- ACSBG1 | c.1008C>T p.Y336= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as rs754254013, COSV99357915; called by muse, mutect2, varscan2
- ARHGEF11 | c.3144C>T p.T1048= | Silent (SNP) | VAF 9/109 reads (8%) | catalogued as rs758117629, COSV100169093; called by muse, mutect2
- CACNA1A | c.996G>A p.G332= | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as COSV100803521; called by muse, mutect2, varscan2
- ESR1 | c.1416G>A p.K472= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV99241894; called by muse, mutect2, varscan2
- GPKOW | c.69C>T p.F23= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV99332856; called by muse, mutect2, varscan2
- IL4I1 | c.1482C>G p.V494= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV99681010; called by muse, mutect2, varscan2
- SLC24A3 | c.1098C>T p.N366= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs370751183; called by muse, mutect2, varscan2
- YES1 | c.429G>A p.P143= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs1215306652, COSV100100054; called by muse, mutect2, varscan2
- YTHDF1 | c.1302C>A p.V434= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV100945650; called by muse, mutect2
- CPLANE1 | c.*4928C>T | 3'UTR (SNP) | VAF 23/89 reads (26%) | catalogued as COSV99952130; called by muse, mutect2, varscan2
- FAM174C | c.*183A>G | 3'UTR (SNP) | VAF 32/63 reads (51%) | catalogued as COSV101331235; called by muse, mutect2, varscan2
- WNT4 | c.313+2332G>A | Intron (SNP) | VAF 29/71 reads (41%) | called by muse, mutect2, varscan2
